Somatic mutation profile of tumor specimen MMRF_2762_1_BM_CD138pos (aliquot MMRF_2762_1_BM_CD138pos_T1_KHS5U_L15714) from MMRF case MMRF_2762, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,375 days).
Specimen MMRF_2762_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53c8d7fa-be44-435f-a110-c4d453cf0267.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2762_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2762_1_PB_WBC_C3_KHS5U_L15758; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fe67e7e-09df-44cb-976a-91c705c9bbe1

The open-access MAF lists 271 somatic variants for this specimen: 96 protein-altering or splice-affecting, 37 silent, 138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, 3'UTR 75, Intron 39, Silent 37, 5'UTR 10, Nonsense Mutation 10, RNA 8, 5'Flank 4, Splice Region 4, 3'Flank 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APP | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201085152; called by muse, mutect2, varscan2
- BCL2L13 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 163/372 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs1342224674, COSV100456244; called by muse, mutect2, varscan2
- CCDC171 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV52647334; called by muse, mutect2, varscan2
- CHDH | c.651G>C p.M217I | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as rs1260289930; called by muse, mutect2
- CHRM5 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101271950; called by muse, mutect2, varscan2
- CIC | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV50567647; called by muse, mutect2, varscan2
- CUX2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs765779977, COSV55635837; called by muse, mutect2, varscan2
- CYLD | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV61094598, COSV61094741; called by muse, mutect2, varscan2
- CYLD | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV61095154; called by muse, varscan2
- DISP3 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs188245470, COSV53829936; called by muse, mutect2, varscan2
- DNAH14 | c.7984G>T p.A2662S (on ENST00000445597; = p.A3465S on NM_001367479.1) | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1226200619; called by muse, mutect2, varscan2
- DNHD1 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs551218756; called by muse, mutect2, varscan2
- ELL3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1183839303; called by muse, mutect2, varscan2
- EPHA1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs755258725, COSV51974471, COSV51977919; called by muse, mutect2, varscan2
- EPHB1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs533462328, COSV67662549; called by muse, mutect2, varscan2
- FAM126B | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.826); catalogued as COSV53772045; called by muse, mutect2
- FAT3 | c.11824C>T p.R3942W | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.847); catalogued as rs190745363, COSV53110854; called by muse, mutect2, varscan2
- FCRL5 | c.1868_1871del p.S623* | Frame Shift Del (DEL) | VAF 181/329 reads (55%) | catalogued as rs1368998778; called by mutect2, pindel, varscan2
- GRM8 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 105/258 reads (41%) | catalogued as rs777517253, COSV58819839; called by muse, mutect2, varscan2
- HHAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs143700139; called by muse, mutect2, varscan2
- IGF2BP1 | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.622); catalogued as COSV51731658; called by muse, mutect2, varscan2
- IGHV2-70 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs374376585; called by muse, mutect2, varscan2
- IL4I1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as rs373616117; called by muse, mutect2, varscan2
- ITPKC | c.1308T>G p.C436W | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1481311927; called by muse, mutect2, varscan2
- KIF9 | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 165/362 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs144401798; called by muse, mutect2, varscan2
- KRTAP4-11 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1218655024; called by muse, mutect2
- LGALS14 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs756014059; called by muse, mutect2, varscan2
- LRP3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752717936; called by muse, mutect2, varscan2
- LRRN2 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV65784311; called by muse, mutect2, varscan2
- MC3R | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371354428, COSV54763722; called by muse, mutect2, varscan2
- MDFIC | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1362372654, COSV57566700; called by muse, mutect2, varscan2
- NUP98 | c.3007G>T p.E1003* (on ENST00000359171 / NM_001365126.1; = p.E986* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV61436341; called by muse, mutect2, varscan2
- OR10AG1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV56634032; called by muse, mutect2, varscan2
- POT1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62934256; called by muse, mutect2, varscan2
- PPP1R18 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs781447050; called by muse, mutect2, varscan2
- PROKR1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV58139369; called by muse, mutect2, varscan2
- RUNX2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as CM104824, COSV61842300; called by muse, mutect2, varscan2
- SIRT3 | c.282-3C>T | Splice Region (SNP) | VAF 17/594 reads (3%) | catalogued as rs1231939576; called by muse, mutect2
- SPATA16 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV63529753; called by muse, mutect2, varscan2
- SPATA31D1 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs563411353, COSV61198095; called by muse, mutect2
- SPIDR | c.1934C>T p.T645I | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1242920813; called by muse, mutect2
- TBC1D1 | c.2833C>T p.H945Y | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1260424785; called by muse, mutect2
- TNRC18 | c.8464G>A p.G2822R | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342472551, COSV100078942, COSV60307185; called by muse, varscan2
- UBE2Q1 | c.552C>G p.D184E | Missense Mutation (SNP) | VAF 95/129 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs372396696; called by muse, mutect2, varscan2
- ZBTB1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.077); catalogued as COSV62437463; called by muse, mutect2
- ZFP2 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1245161817; called by muse, mutect2, varscan2
- ACSM1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACVR2A | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- AFG3L2 | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.9626C>T p.S3209F | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- BRIP1 | c.3390C>G p.I1130M | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- C2CD6 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CBLIF | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL18A1 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CORO6 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DIS3 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF4G2 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- ETS2 | c.1121C>G p.S374* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- FAM219B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2
- FASN | c.2055C>G p.Y685* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- FNDC3A | c.796_798del p.L266del (on ENST00000492622 / NM_001079673.2; = p.L210del on NM_014923.5) | In Frame Del (DEL) | VAF 26/33 reads (79%) | called by pindel, varscan2
- FOSL1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2
- GART | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBE1 | c.884A>C p.N295T | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIPC3 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GOLGB1 | c.5071G>C p.E1691Q | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPD2 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- HEATR9 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ITGB1BP2 | c.540-3C>T | Splice Region (SNP) | VAF 65/73 reads (89%) | called by muse, mutect2, varscan2
- KANSL3 | c.1895C>A p.S632* (on ENST00000666923 / NM_001349262.2; = p.S606* on NM_001115016.3) | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4052C>G p.S1351C | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- LILRB4 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, varscan2
- LRRC8C | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2
- MANF | c.491T>G p.I164R | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ME3 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFYC | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NPHS1 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NRARP | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 113/248 reads (46%) | called by muse, mutect2, varscan2
- PCDH9 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- PCDHB3 | c.811A>C p.T271P | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- PLEKHS1 | c.857A>G p.E286G (on ENST00000369310 / NM_182601.1; = p.E292G on NM_024889.5) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- PPP4R4 | c.189C>G p.L63= | Splice Region (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- PRKDC | c.5849C>T p.S1950F | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PSMD1 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RFXAP | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SDR39U1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SH2B2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC37A1 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TLCD4-RWDD3 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); called by muse, mutect2
- TNNT1 | c.73+3G>A | Splice Region (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- TRIM33 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- UBE2J1 | c.31+2T>C p.X11_splice | Splice Site (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- UFL1 | c.888G>C p.L296F | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZRSR2 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARF4 | c.496C>T p.L166= | Silent (SNP) | VAF 102/221 reads (46%) | called by muse, mutect2, varscan2
- ASL | c.417C>T p.L139= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- C1orf87 | c.1437G>A p.R479= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as rs1229483126; called by muse, mutect2, varscan2
- CDH15 | c.732C>T p.A244= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- CEACAM1 | c.621G>A p.R207= | Silent (SNP) | VAF 158/344 reads (46%) | catalogued as COSV50726130; called by muse, mutect2, varscan2
- CISD2 | c.183G>A p.P61= | Silent (SNP) | VAF 151/353 reads (43%) | catalogued as rs199702688; called by muse, mutect2, varscan2
- DPP9 | c.1518C>T p.V506= (on ENST00000598800; = p.V535= on NM_139159.5) | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- FGD5 | c.2502G>A p.Q834= | Silent (SNP) | VAF 75/168 reads (45%) | catalogued as COSV99547704; called by muse, mutect2, varscan2
- GART | c.1584A>G p.G528= | Silent (SNP) | VAF 69/151 reads (46%) | catalogued as rs1172162214; called by muse, mutect2, varscan2
- GNL3 | c.1053G>A p.L351= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- GOLT1A | c.144C>T p.L48= | Silent (SNP) | VAF 11/173 reads (6%) | catalogued as COSV57644336; called by muse, mutect2
- HDAC5 | c.294C>T p.F98= | Silent (SNP) | VAF 93/241 reads (39%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1860G>A p.A620= | Silent (SNP) | VAF 83/219 reads (38%) | catalogued as rs1240166289; called by muse, mutect2, varscan2
- ICE1 | c.1311G>A p.V437= | Silent (SNP) | VAF 21/288 reads (7%) | called by muse, mutect2
- ID2 | c.33G>A p.R11= | Silent (SNP) | VAF 110/269 reads (41%) | catalogued as rs746017528, COSV52169591; called by muse, mutect2, varscan2
- MAF | c.204C>T p.P68= | Silent (SNP) | VAF 36/48 reads (75%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2895G>A p.L965= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53582835; called by muse, mutect2, varscan2
- MGAM2 | c.2082C>T p.F694= | Silent (SNP) | VAF 70/174 reads (40%) | called by muse, mutect2, varscan2
- MRPS26 | c.168G>A p.L56= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- MUC16 | c.20580G>A p.L6860= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- NHLH1 | c.304C>T p.L102= | Silent (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- NISCH | c.4401C>T p.V1467= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- PEG10 | c.843G>C p.L281= (on ENST00000482108 / NM_001040152.2; = p.L315= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/152 reads (49%) | called by muse, mutect2, varscan2
- PREX1 | c.1864C>T p.L622= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs774681439, COSV64256651; called by muse, mutect2, varscan2
- PRKD1 | c.408C>T p.S136= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as rs747688196, COSV100118926; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.258G>A p.K86= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as rs779684897; called by muse, mutect2, varscan2
- SFTPA1 | c.603A>C p.S201= | Silent (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- SMARCAD1 | c.12C>T p.F4= | Silent (SNP) | VAF 113/286 reads (40%) | called by muse, mutect2, varscan2
- SORCS3 | c.1383C>T p.L461= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV100865700; called by muse, mutect2, varscan2
- SYDE2 | c.2043C>T p.L681= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- TBC1D25 | c.1032C>T p.V344= | Silent (SNP) | VAF 145/164 reads (88%) | catalogued as rs782045199; called by muse, mutect2, varscan2
- TET1 | c.2331C>T p.F777= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs1170457819, COSV65383087; called by muse, mutect2, varscan2
- THOP1 | c.1647C>T p.L549= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- TIMM10B | c.210C>G p.L70= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV99601451; called by muse, mutect2, varscan2
- TTC21A | c.3954G>A p.L1318= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs756787380; called by muse, mutect2, varscan2
- TTN | c.100860G>A p.P33620= (on ENST00000591111; = p.P26196= on NM_003319.4) | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs556765365, COSV100630248; ClinVar: likely benign; called by muse, mutect2
- VPS33A | c.1485C>T p.L495= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1354266418, COSV57359273; called by muse, mutect2, varscan2
- AC026410.1 | n.813C>T | RNA (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- ACSL3 | c.*2317C>G | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+610C>T | Intron (SNP) | VAF 40/69 reads (58%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.*1015C>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- ANKFN1 | c.*70G>C | 3'UTR (SNP) | VAF 102/241 reads (42%) | catalogued as COSV100593200; called by muse, mutect2, varscan2
- ANO1 | c.1950+233G>A | Intron (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- ARHGAP31 | c.-190G>A | 5'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- ARMCX3 | c.*283G>A | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- ARSI | c.-525C>T | 5'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- ATP1B4 | c.*1392C>G | 3'UTR (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96091189 G>A | 3'Flank (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- C1QTNF1 | chr17:79019326 T>A | 5'Flank (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- C1orf21 | c.*648C>G | 3'UTR (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- C5orf60 | n.2305C>A | RNA (SNP) | VAF 106/282 reads (38%) | called by muse, mutect2, varscan2
- CACNB2 | c.214-61136A>T | Intron (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- CCND2 | c.*4958C>G | 3'UTR (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99714365; called by muse, mutect2, varscan2
- CD226 | c.*2293C>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- CDC42EP1 | c.-107C>A | 5'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- CFAP298 | c.762+144G>C | Intron (SNP) | VAF 109/291 reads (37%) | called by muse, mutect2, varscan2
- CLDN1 | c.*235G>A | 3'UTR (SNP) | VAF 16/29 reads (55%) | catalogued as rs923159836; called by muse, mutect2, varscan2
- CLDND1 | c.-57G>A | 5'UTR (SNP) | VAF 123/310 reads (40%) | catalogued as rs1258183890; called by muse, mutect2, varscan2
- CLIP2 | c.*701G>T | 3'UTR (SNP) | VAF 119/307 reads (39%) | called by muse, mutect2, varscan2
- COQ10A | c.475-37A>C | Intron (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- CPSF2 | c.*196C>T | 3'UTR (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- CUL5 | c.*3031T>G | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415328 C>T | 5'Flank (SNP) | VAF 19/302 reads (6%) | catalogued as COSV52567086; called by muse, mutect2
- DDIT4L | c.*1101C>T | 3'UTR (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- DENND2D | c.68-35G>A | Intron (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- DNAJA1 | c.*713C>T | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- DONSON | c.-15C>T | 5'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- DUS4L-BCAP29 | c.-111+134G>A | Intron (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- DYRK2 | c.*1746dup | 3'UTR (INS) | VAF 40/93 reads (43%) | called by mutect2, varscan2
- EIF2AK3 | c.*963C>G | 3'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as rs1382124151; called by muse, mutect2, varscan2
- EIF4A1 | c.997-54C>T | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- ELFN2 | c.*2301G>A | 3'UTR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- ERCC6 | c.*3174G>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- EXOC8 | c.*765G>C | 3'UTR (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- FBN2 | c.*774G>A | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- FLRT2 | chr14:85529052 G>T | 5'Flank (SNP) | VAF 102/207 reads (49%) | called by mutect2, varscan2
- FMO9P | n.473T>C | RNA (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- G3BP2 | c.*147G>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as rs1171371291; called by muse, mutect2, varscan2
- GNA12 | c.*2187G>A | 3'UTR (SNP) | VAF 65/159 reads (41%) | catalogued as rs1186755339; called by muse, mutect2, varscan2
- GOLPH3L | c.*1868T>C | 3'UTR (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- GRB10 | c.*1C>T | 3'UTR (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- GTPBP10 | c.*3016G>C | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs907295685; called by muse, mutect2, varscan2
- HAS2 | c.*609G>A | 3'UTR (SNP) | VAF 9/115 reads (8%) | catalogued as rs956571058; called by muse, mutect2
- HHIPL1 | c.1730+852C>T | Intron (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- HIVEP1 | c.40+23431C>G | Intron (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- IAH1 | c.81+504G>C | Intron (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- IL1RL1 | c.971-2236G>A | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- IRF6 | c.*985G>C | 3'UTR (SNP) | VAF 47/258 reads (18%) | called by muse, mutect2, varscan2
- ITGA3 | c.*1378G>A | 3'UTR (SNP) | VAF 16/245 reads (7%) | catalogued as rs1035928112; called by muse, mutect2
- KCNMA1 | c.2709+17A>T | Intron (SNP) | VAF 79/197 reads (40%) | catalogued as rs777013289; called by muse, mutect2, varscan2
- KCNQ4 | c.*1065G>T | 3'UTR (SNP) | VAF 99/231 reads (43%) | called by muse, mutect2, varscan2
- KLC4 | c.-26+486C>G | Intron (SNP) | VAF 85/220 reads (39%) | called by muse, mutect2, varscan2
- KPNA4 | c.*1905G>A | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- LARP1 | c.*2954G>A | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2
- LTB | c.162+137C>T | Intron (SNP) | VAF 29/58 reads (50%) | catalogued as rs186447095, COSV53001762; called by muse, mutect2, varscan2
- MAT2A | c.*64G>A | 3'UTR (SNP) | VAF 65/166 reads (39%) | called by muse, mutect2, varscan2
- MIR296 | n.30C>G | RNA (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- MOSPD2 | c.*1798A>G | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- MROH7 | c.2965-1992C>T | Intron (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- MRPL42 | c.*91-638T>C | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- NECTIN1 | c.1003+571G>C | Intron (SNP) | VAF 13/415 reads (3%) | called by muse, mutect2
- NLN | c.*2920_*2932del | 3'UTR (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- NRARP | c.*712G>A | 3'UTR (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- NSUN3 | c.*575G>A | 3'UTR (SNP) | VAF 61/135 reads (45%) | called by muse, mutect2, varscan2
- NWD2 | c.-199G>C | 5'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- OAS3 | chr12:112938460 G>A | 5'Flank (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- OR2A13P | n.850C>T | RNA (SNP) | VAF 114/247 reads (46%) | called by muse, mutect2, varscan2
- OTUD4 | c.*3237C>T | 3'UTR (SNP) | VAF 10/288 reads (3%) | called by muse, mutect2
- PAFAH1B1 | c.1160-74G>A | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- PDCD10 | c.*749G>C | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91481C>A | Intron (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- PEX19 | c.*396G>A | 3'UTR (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- PGR | c.*7576G>C | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- PHC3 | c.537+629T>A | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- PLCXD1 | c.*3014C>A | 3'UTR (SNP) | VAF 71/141 reads (50%) | called by muse, mutect2, varscan2
- PMVK | c.-16G>A | 5'UTR (SNP) | VAF 17/248 reads (7%) | catalogued as COSV100870514; called by muse, mutect2
- PPFIA1 | c.2865+3267G>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- PPP5C | c.634-161G>A | Intron (SNP) | VAF 34/86 reads (40%) | catalogued as rs572086663, COSV50141503; called by muse, varscan2
- PRRX1 | c.*2115T>G | 3'UTR (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- PSAP | c.*654G>A | 3'UTR (SNP) | VAF 49/170 reads (29%) | catalogued as rs41282246; called by muse, mutect2, varscan2
- PSMG4 | c.251-1130C>T | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PTPRR | c.358-24075G>A | Intron (SNP) | VAF 138/348 reads (40%) | called by muse, mutect2, varscan2
- RABEP2 | c.62-160T>C | Intron (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- RALGPS2 | c.*165G>C | 3'UTR (SNP) | VAF 7/212 reads (3%) | catalogued as COSV62683091; called by muse, mutect2
- RASGRF2 | c.*2238G>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- RBM38 | c.238-170G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- RFX3 | c.*5397G>C | 3'UTR (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- RGS11 | c.318+216C>T | Intron (SNP) | VAF 86/106 reads (81%) | called by muse, mutect2, varscan2
- RNF152 | c.*5054C>T | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ROBO4 | c.1548-89C>T | Intron (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- RPL26P30 | n.639C>T | RNA (SNP) | VAF 21/352 reads (6%) | catalogued as rs773062550; called by muse, mutect2
- RRM2B | c.*3086T>C | 3'UTR (SNP) | VAF 15/399 reads (4%) | catalogued as rs1364817278; called by muse, mutect2
- RUNX2 | c.*3447G>A | 3'UTR (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- RUNX3 | c.*2438G>A | 3'UTR (SNP) | VAF 53/120 reads (44%) | catalogued as rs916823792; called by muse, mutect2, varscan2
- SELENOI | c.*2215C>G | 3'UTR (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- SEMA3A | c.*2379C>A | 3'UTR (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- SETD2 | chr3:47012403 C>T | 3'Flank (SNP) | VAF 52/142 reads (37%) | called by muse, mutect2, varscan2
- SFXN5 | c.*2229C>T | 3'UTR (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- SGCE | c.572-17T>C | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as COSV56019431; called by muse, mutect2
- SH3GL1P2 | n.1050C>T | RNA (SNP) | VAF 65/142 reads (46%) | catalogued as rs1303238290; called by muse, mutect2, varscan2
- SIRT7 | c.481-75C>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs1053108217; called by muse, mutect2
- SLC22A20P | n.1081+2125_1081+2146del | Intron (DEL) | VAF 24/91 reads (26%) | called by mutect2, varscan2
- SLC5A3 | c.*8522_*8535del | 3'UTR (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- SNRPD3 | c.*806G>A | 3'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as rs913196336; called by muse, mutect2, varscan2
- STK32B | c.108+250G>A | Intron (SNP) | VAF 34/88 reads (39%) | catalogued as rs764391198; called by muse, mutect2, varscan2
- SZT2 | c.*3636G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- TECRL | c.*1747T>C | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2
- TFF1 | c.*170C>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | catalogued as rs1280640423; called by muse, mutect2, varscan2
- TIFAB | c.*1825G>A | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- TLK1 | c.*421T>C | 3'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as rs915127216; called by muse, mutect2, varscan2
- TMEM108 | c.1451-1183G>T | Intron (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- TMEM132D | c.*176C>T | 3'UTR (SNP) | VAF 55/115 reads (48%) | catalogued as rs916090596; called by muse, mutect2, varscan2
- TNK2 | c.235-546C>A | Intron (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- TNKS2 | c.*708G>A | 3'UTR (SNP) | VAF 32/90 reads (36%) | called by mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 43/96 reads (45%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
- TOR1AIP2 | c.*3564G>C | 3'UTR (SNP) | VAF 34/153 reads (22%) | called by muse, mutect2, varscan2
- TRIM11 | c.*559G>C | 3'UTR (SNP) | VAF 67/360 reads (19%) | called by muse, mutect2, varscan2
- TRIM42 | c.-51T>C | 5'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- TRIM47 | c.772-107C>T | Intron (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- TRIM6 | c.*1191G>A | 3'UTR (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- TSC22D1 | c.2913-748G>A | Intron (SNP) | VAF 43/58 reads (74%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.*295C>G | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- USP49 | c.*1600G>A | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- WFDC1 | c.*15+94G>A | Intron (SNP) | VAF 36/39 reads (92%) | catalogued as rs913858350; called by muse, mutect2, varscan2
- WNK3 | c.*5047G>A | 3'UTR (SNP) | VAF 26/32 reads (81%) | called by muse, mutect2, varscan2
- WWC1 | c.*1222A>T | 3'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- XKR4 | c.*98G>A | 3'UTR (SNP) | VAF 57/184 reads (31%) | catalogued as rs903545044, COSV59316082; called by muse, mutect2, varscan2
- ZFP62 | c.*113G>C | 3'UTR (SNP) | VAF 12/221 reads (5%) | called by muse, mutect2
- ZNF233 | c.-98G>A | 5'UTR (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- ZNF260 | c.*3181G>T | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ZNF704 | c.*2719G>A | 3'UTR (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- ZNF765 | c.*861G>A | 3'UTR (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- ZNF791 | c.*523G>A | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- ZNF890P | n.932A>C | RNA (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- ZNRF3 | c.-73C>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
